Surgical pathology report (de-identified scan), TCGA case TCGA-23-2647, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Cedars Sinai, specimen TCGA-23-2647-01A (Primary Tumor).

[page 1 of 11]
SURGICAL PATHOLOGY REPORT

***** Addendum - Please See End of Report *****

Reason for Addendum #1: Additional sections or studies

SYNOPSIS REPORT:

Applies To:

A : OMENTUM #1

B : OMENTUM #2

C : RIGHT COLON TUMOR

D : BLADDER FLAP

E : LEFT TUBE & OVARY

F : RIGHT TUBE & OVARY

G : UTERUS

H : SIDE WALL TUMOR

I : EPIPLOIC

J : ANTERIOR ABD. WALL

M : CECUM TUMOR

Macroscopic

Specimen Type:

Left and right ovaries

Left and right fallopian tubes

Uterus

Omentum

Peritoneum

Pericolic and perivesical tissues.

Procedure:

Right salpingo-oophorectomy

Left salpingo-oophorectomy

Hysterectomy

Omentectomy

Peritoneal biopsies

Specimen integrity, right ovary:

Intact

Specimen integrity, left ovary:

Intact

Microscopic

Histologic Type:

Serous adenocarcinoma

Histologic Grade:

G3: Poorly differentiated

Primary tumor site:

Right ovary

Tumor Size:

Right ovarian tumor, greatest dimension: 0.8cm

Comment(s): Largest intraparenchymal tumor nodule in right ovary is 0.8 cm in diameter. Ovary together with serosal tumor is 4.0 cm in maximum dimension.

Ovarian surface involvement:

Present

[page 2 of 11]
Summary of Organs/Tissues Microscopically

Involved by Tumor: Both ovaries
Fallopian tube(s)
Omentum
Uterus
Peritoneum
Pericolic tissues

Lymphovascular Invasion: Present

Primary Tumor (pT): pT3c : Macroscopic peritoneal metastasis beyond pelvis more than 2 cm in greatest dimension and/or regional lymph node metastasis

Regional Lymph Nodes (pN): pNX: Cannot be assessed

Number of lymph nodes identified: 0

Number of lymph nodes involved: 0

Additional Pathologic Findings

High grade serous epithelial dysplasia/serous intraepithelial carcinoma involving fimbriated end of left fallopiann tube.

DIAGNOSIS:

A. OMENTUM, "#1", PARTIAL OMENECTOMY:

- Extensive involvement by metastatic serous carcinoma (see comment)

B. OMENTUM, "#2", PARTIAL OMENECTOMY:

- Metastatic serous carcinoma (see comment)

C. SPECIMEN DESIGNATED "RIGHT COLON TUMOR", EXCISION:

- Metastatic serous carcinoma (see comment)
- No colonic tissue identified

D. [SOFT TISSUE], BLADDER FLAP, EXCISION:

- Metastatic serous carcinoma (see comment)

E. FALLOPIAN TUBE AND OVARY, LEFT, SALPINGO-OOPHORECTOMY:

- Atrophic ovary with extensive serosal surface involvement by high-grade serous carcinoma, and several nodular aggregates of carcinoma invading underlying ovarian parenchyma, latter up to 0.35 cm in diameter
- Metastatic serous carcinoma involving serosal surface of fallopian tube, and paratubal and paraovarian ligamentous soft tissues, and regional lymphatics
- Ovary also shows cystic epithelial inclusions, deep surface epithelial clefts, focal benign microscopic surface papillary adenofibromatous changes, and serosal adhesions
- Fallopian tube also shows chronic inflammation, serosal adhesions, few detached fragments of serous carcinoma cells within lumen, foci of epithelial hyperplasia with and without atypia, and focal high-grade epithelial dysplasia/serous intraepithelial carcinoma at fimbriated end of fallopian tube (see comment)

[page 3 of 11]
F. FALLOPIAN TUBE AND OVARY, RIGHT, SALPINGO-OOPHORECTOMY:

- Atrophic ovary with extensive serosal surface involvement by high-grade serous carcinoma and multiple invasive tumor deposits within ovarian parenchyma, the latter of which measure up to 0.8 cm in diameter
- Fallopian tube shows serosal/subserosal involvement by metastatic serous carcinoma and a detached less than 0.4 cm diameter aggregate of mostly necrotic and some viable tumor cells admixed with fibrinous material in lumen in mid portion of fallopian tube and detached fragments of carcinoma cells adjacent to fimbriated end of the fallopian tube
- Extensive involvement of paraovarian and paratubal ligamentous tissues by metastatic serous carcinoma
- Lymphovascular invasion by carcinoma is also present
- Ovary also shows a hemorrhagic cystic corpus luteum, accumulations of hemosiderin-laden macrophages, cystic epithelial inclusions, secondary inflammatory changes, and serosal adhesions
- Fallopian tube also shows chronic and minimal acute inflammation, serosal adhesions, and foci of epithelial hyperplasia without significant cellular atypia

G. UTERUS, TOTAL ABDOMINAL HYSTERECTOMY:

- Metastatic serous carcinoma extensively involving uterine serosa, also involving subserosa of uterus, and invading lymphovascular spaces in uterine and cervical wall
- Uterine leiomyomas
- Benign endometrial polyp
- Endometrium with weakly proliferative to proliferative features
- Adenomyosis
- Cervix also shows, acute and chronic inflammation, secondary reactive epithelial changes, subepithelial hemorrhages, squamous metaplasia, accumulations of hemosiderin-laden macrophages in stroma, reserve cell hyperplasia, endocervical tunnel clusters, and nabothian cysts
- Vaginal cuff with mild chronic inflammation of mucosa

H. SOFT TISSUE, DESIGNATED "SIDE WALL TUMOR", EXCISION:

- Extensive involvement by metastatic serous carcinoma (see comment)

I. SOFT TISSUE, EPIPLOIC [ADIPOSE TISSUE], EXCISION:

- Extensive involvement by metastatic serous carcinoma (see comment)

J. SOFT TISSUE, ANTERIOR ABDOMINAL WALL, EXCISION:

- Metastatic serous carcinoma (see comment)

K. THE CANCER GENOME ATLAS () STUDY:

- High-grade serous carcinoma involving serosa of ovary, focally invading ovary, and paraovarian soft tissues in right adnexa; all three specimens (slides K1-K3) are involved
- A (slide K1) with:
- 25% tumor cell nuclei
- Less than 10% tumor cell necrosis
- B (slide K2) with:
- About 50% tumor cell nuclei
- Less than 10% tumor cell necrosis

[page 4 of 11]
- [REDACTED] A C (slide K3) with:
- About 20% tumor cell nuclei
- Less than 10% tumor cell necrosis

L. [REDACTED] [REDACTED]:

- High-grade serous carcinoma extensively involving omentum in all three sections (slides L1, L2, L3)
- Slide L1 [REDACTED] with:
- About 70% to 75% tumor cell nuclei
- Less than 10% tumor cell necrosis
- Slide [REDACTED] with:
- About 60% tumor cell nuclei
- Less than 10% tumor cell necrosis
- Slide [REDACTED] with:
- About 50% tumor cell nuclei
- Less than 10% tumor cell necrosis
- High-grade serous carcinoma involving serosa of left ovary and paraovarian tissues; sections from all three slides of left ovary are involved
- Slide [REDACTED] left ovary with less than 10% tumor cell nuclei
- Less than 10% tumor cell necrosis
- Slide [REDACTED] left ovary B with 20% tumor cell nuclei
- Less than 10% tumor cell necrosis
- Slide [REDACTED] C left ovary with:
- 15% tumor cell nuclei
- Less than 10% tumor cell necrosis

M. [SOFT TISSUE, PERICOLIC], SPECIMEN DESIGNATED "CECUM TUMOR":

- Metastatic serous carcinoma (see comment)
- No colonic tissue identified

COMMENT: Both ovaries are atrophic and each shows extensive (mostly) serosal surface involvement by serous carcinoma. In both ovaries, there are small nodular aggregates of tumor within ovarian parenchyma. In the right ovary the maximum dimension of invasive tumor in the ovary is about 0.8 cm; thereby, qualifying by currently established criteria as a right ovarian primary neoplasm. Tumor in all involved sites exhibits features of high-grade serous carcinoma. Lymphovascular invasion by carcinoma is present in most of the involved sites. Tumor-associated necrosis, fibrosing stromal reaction to tumor, acute and chronic inflammatory changes, adhesions, and secondary reactive mesothelial proliferation are also noted in vicinity of tumor in many of the involved sites. The focus of high-grade epithelial dysplasia/serous intraepithelial carcinoma involving the fimbriated end of the left fallopian tube may represent a serous primary neoplasm. Preliminary pathologic findings were conveyed to [REDACTED]

HISTORY: [REDACTED]
"Ovarian cancer"; possible primary peritoneal carcinoma

MICROSCOPIC FINDINGS: [REDACTED]
See diagnosis.

[page 5 of 11]
SPECIAL STUDIES:

H&E-stained short step sections (G6 x1, G8 x1)

IMMUNOHISTOCHEMISTRY:

Study / Antibody	Block	Result
P53	E1	Metastatic serous carcinoma cells exhibit positive nuclear staining. No evidence of p53 signature profile of native tubal epithelial cells, i.e. no runs of 6 or more consecutive positive tubal epithelial cell in the proximal segment of the left fallopian tube.
P53	E3	Positive p53 signature profile involving native tubal epithelial cells (greater than 6 consecutive positive nuclei) in lesions at fimbriated end of the left fallopian tube.
P53	F1	Metastatic serous carcinoma cells exhibit positive staining. No evidence of p53 signature profile for native tubal epithelial cells in the proximal segment of the right fallopian tube.
P53	F3	Positive staining of serous carcinoma cells in detached fragment of tumor adjacent to fimbriated end of right fallopian tube. No evidence of p53 signature profile for native tubal epithelial cells in the proximal segment of the right fallopian tube.

GROSS:**A. OMENTUM #1**

Labeled with the patient's name, labeled "omentum #1", and received fresh in the Operating Room for frozen section, and subsequently fixed in formalin, is about a 190 gram, 20.0 x 14.0 x 3.0 cm partial omentectomy specimen. The specimen is received in several fragments. The individual fragments range from 2.0 to 12.0 cm in maximum dimension.

Each of the fragments is indurated due to the presence of nodular and plaque-like deposits of firm white-tan tumor.

Representative sections are submitted.

Slide key:

A1. Remnant of frozen section A1 - 2

A2. Unfrozen omentum with tumor - 2

B. OMENTUM #2

Labeled with the patient's name, labeled "omentum #2", and received in formalin is about a 200 gram, 24.0 x 13.0 x 2.5 cm partial omentectomy specimen. Also received are two smaller portions of omentum that are about 2.5 and 3.5 cm in maximum dimension.

Each of the portions of omental tissue are remarkable for extensive involvement by nodular and plaque-like aggregates of firm white to yellow tumor.

Representative sections are submitted.

Slide key:

B1. Omentum with tumor - 2

C. RIGHT COLON TUMOR

[page 6 of 11]
[REDACTED]

Labeled with the patient's name, labeled "right colon tumor", and received in formalin is a 2.0 x 1.0 x 0.8 cm portion of yellow-tan fatty tissue.

The tissue fragment is subtotally replaced by firm tan-white tumor.

Entirely submitted.

Slide key:

C1. Tumor - 2

D. BLADDER FLAP

Labeled with the patient's name, labeled "bladder flap", and received in formalin are four portions of tan-yellow soft tissue ranging from 1.0 to 2.0 cm in maximum dimension and amounting in aggregate to about 3.0 x 2.5 x 1.5 cm.

The soft tissues show partial replacement by firm tan-white tumor.

Representative sections are submitted.

Slide key:

D1. Soft tissues with tumor - 4

E. LEFT TUBE AND OVARY

Labeled with the patient's name, labeled "left tube and ovary", and received fresh in the Operating Room and subsequently fixed in formalin is about a 15.6 gram salpingo-oophorectomy specimen. The ovary is about 4.5 x 2.5 x 1.5 cm. The fimbriated fallopian tube is about 5.5 cm long and ranges from 0.4 to 0.6 cm in diameter.

The overall dimensions of the ovary include multiple plaque-like and nodular aggregates of semifirm to firm tan-white tumor deposits on the serosal surface of the ovary. Within the ovary there is about a 0.3 cm similar-appearing tumor nodule in the cortex. The deposits of plaque-like and nodular aggregates of similar-appearing semisoft to firm tan tumor are also present on the serosal surface of the fallopian tube and within the para-ovarian and paratubal ligamentous soft tissues.

The ovary also shows several minute to small cysts, the largest of which is about 0.7 cm in diameter. No pathologic lesions of the fallopian tube are seen.

Entirely embedded.

Slide key:

E1. Proximal fallopian tube - 3

E2. Mid fallopian tube - 3

E3. Distal fimbriated fallopian tube - 2

E4, E5. Ovary - 2 each

E6-E9. Ovary - 1 each

F. RIGHT TUBE AND OVARY

Labeled with the patient's name, labeled "right tube and ovary", and received fresh in the Operating Room and subsequently fixed in formalin is about a 20.3 gram salpingo-oophorectomy specimen. The fimbriated fallopian tube is about 5.3 cm long and ranges from 0.3 to 0.6 cm in diameter. The ovary is about 4.0 x 1.8 x 1.5 cm.

The dimensions of the ovary include the ovary proper and nodular and plaque-like aggregates of semisoft to firm tan tumor on the surface of the ovary. Within the ovarian parenchyma there are also small nodular

[page 7 of 11]
[REDACTED]

tumor deposits, the largest of which is about 0.8 cm in diameter. The adnexal ligaments are also extensively involved by similar-appearing nodular and plaque-like aggregates of semisoft to firm tan-white tumor. The ligamentous tissue together with the tumor deposits is about 5.0 x 2.5 x 1.5 cm. No gross tumor is seen in the fallopian tube.

The ovary also shows about a 1.0 cm diameter amber corpus luteum cyst containing blood.

Entirely embedded.

Slide key:

- F1. Proximal fallopian tube - 3
- F2. Mid fallopian tube - 4
- F3. Distal fallopian tube - 3
- F4. Ovary and paraovarian tissues - 4
- F5-F11. Ovary and adnexal soft tissues - 1 each
- F12-F14. Ovary and adnexal soft tissues - 2 each

G. UTERUS

Labeled with the patient's name, labeled "uterus", and received fresh in the Operating Room for intraoperative gross consultation and subsequently fixed in formalin, is about a 260 gram intact total hysterectomy specimen. The uterus is about 11.0 x 7.5 x 7.5 cm in greatest overall dimensions. The cervical portion of the uterus is about 4.0 cm long and up to 4.0 cm in diameter with a 0.4 cm diameter external os. Attached to the cervix there is a circumferential cuff of vaginal mucosa that is up to 0.5 cm in length and up to 4.0 cm in diameter. The endometrial cavity is about 5.5 cm long and up to 2.5 cm in width. The flat endometrial mucosa ranges from about 0.1 to 0.15 cm in thickness. The muscular uterine wall ranges from 1.5 to 4.0 cm in thickness.

The uterine serosa shows multiple plaque-like aggregates of semisoft to firm tan and tan-white tumor. No grossly evident metastatic tumor is seen in the wall of the uterus, or in the cervix or vaginal cuff.

The uterus is distorted in shape due to the presence of multiple (about 15 to 20) well-circumscribed leiomyomas. The leiomyoma range from about 0.3 to 3.5 cm in diameter and are intramural. Each leiomyoma is composed of firm white whorled tissue without grossly evident areas of hemorrhage or necrosis. There is a 1.5 x 1.0 x 0.5 cm soft tan endometrial polyp. The endometrium is otherwise grossly unremarkable. The muscular uterine wall shows trabeculations and minute to tiny cystic spaces suggestive of adenomyosis. The cervix is remarkable only for multiple mucus-filled cysts ranging from about 0.2 to 0.7 cm in maximum dimension.

Ink key: inferior surgical margin - blue; outer anterior aspect of uterus - green; outer posterior aspect of uterus - black.

Representative sections are submitted.

Slide key:

- G1. Endometrial polyp - 1
- G2. Anterior cervix - 1
- G3. Anterior lower uterine segment - 1
- G4. Posterior cervix - 2
- G5. Posterior lower uterine segment - 1
- G6. Anterior uterine corpus - 1
- G7. Posterior uterine fundus - 1
- G8. Posterior uterine corpus - 1
- G9. Largest leiomyoma - 1
- G10. Posterior uterine corpus with serosal tumor, adhesions and leiomyoma - 2

[page 8 of 11]
H. SIDE WALL TUMOR

Labeled with the patient's name, labeled "side wall tumor", and received in formalin is about a 2.4 gram aggregate of multiple fragments of tan soft tissue amounting in aggregate to about 4.0 x 1.5 x 1.5 cm.

The soft tissues are largely replaced by nodular and plaque-like aggregates of firm tan-white tumor.

Representative sections are submitted.

Slide key:

H1. Soft tissues with tumor - 4

I. EPIPLOIC

Labeled with the patient's name, labeled "epiploic", and received in formalin are three portions of yellow fatty tissue ranging from about 1.2 to 2.3 cm in maximum dimension and amounting in aggregate to about 2.7 x 2.7 x 1.0 cm.

The fat is largely replaced by deposits of semisoft tan-white tumor.

Representative sections are submitted.

Slide key:

I1. Fatty tissue with tumor - 4

J. ANTERIOR ABDOMINAL WALL

Labeled with the patient's name, labeled "anterior abdominal wall", and received in formalin is a 4.0 x 3.5 x 1.0 cm aggregate of multiple fragments of tan soft tissue admixed with blood clot.

The tissue is partially replaced by deposits of firm tan-white tumor.

Representative sections are submitted.

Slide key:

J1. Soft tissues with tumor and blood clot - 4

K.

Labeled with the patient's name, labeled , and received fresh in the Operating Room for study and subsequently fixed in formalin are six small portions of tissue from the right ovary (taken from specimen F). The individual tissue fragments range from about 0.3 to 0.8 cm in maximum dimension and amount in aggregate to 1.0 x 1.0 x 0.3 cm.

Portions of the tissue were released for research protocol and the remainder are subsequently fixed in formalin and embedded for permanent sections.

Slide key:

L.

Labeled with the patient's name, labeled , and received fresh in the Operating Room for studies, are six portions of ovarian tissue and six portions of omentum, obtained from specimen E and A, respectively. The individual tissue fragments range from about 0.5 to 1.0 cm in maximum dimension and

[page 9 of 11]
[REDACTED]

amount in aggregate to 1.5 x 1.5 x 0.5 cm. Portions of fresh tissue were released for [REDACTED]. The rest of the tissue fragments are subsequently fixed in formalin and embedded for permanent sections.

[REDACTED]

M. CECUM TUMOR

Labeled with the patient's name, labeled "cecum tumor", and received in formalin are three portions of tan-yellow fibrofatty tissue ranging from about 0.3 to 4.0 cm in maximum dimension and amounting in aggregate to 4.0 x 2.5 x 1.0 cm.

The tissue fragments are partially replaced by semifirm aggregates of tan-white tumor.

Representative sections are submitted.

M1. Fibrofatty tissue with tumor - 4

[REDACTED]

INTRAOPERATIVE CONSULTATION
OPERATIVE CALL
OPERATIVE CONSULT (FROZEN):

OMENTUM FROZEN SECTION A:

[REDACTED]

[REDACTED]

[REDACTED]

[page 11 of 11]
ADDENDUM:

RESULT OF ADDITIONAL IMMUNOSTAIN:

Study / Antibody	Block	Result
Ki-67	E3	Most (about 70%) of the dysplastic/neoplastic epithelial cells at the fimbriated end of the fallopian tube exhibit positive nuclear staining. Detached aggregates of serous carcinoma cells adjacent to the fallopian tube also exhibit positive staining. There is also increased staining of some tubal epithelial cells in areas showing hyperplasia.

Source: NCI Genomic Data Commons file d217126d-8269-4ea8-8eb0-4137e5a4d45b (TCGA-23-2647.3DA98ECE-BECE-4409-BE21-A70037DCFD9F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).